TCGA case TCGA-B6-A408 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9964f447-92ad-4d1e-af20-11cf84fab7b0

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct and lobular carcinoma: ICD-O-3 morphology code: 8522/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,102 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N3a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 10; Lymph nodes tested: 23; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Days to treatment start: 55 days; Days to treatment end: 163 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Doxorubicin; Days to treatment start: 58 days; Days to treatment end: 163 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 208 days; Days to treatment end: 244 days; Treatment dose: 4,800 cGy; Number of fractions: 24; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 1,519 days (4.2 years); Disease response: Tumor Free.
- Days to follow up: 2,072 days (5.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 1.2; Cell count: 60; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 2.9; Cell count: 60.
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+; Test value range: 20-29%.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 3+; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity scale: 4 Point Scale; Staining intensity value: 3+; Test value range: 60-69%.
- Test (FISH): Copy Number Reported; Copy number: 2.6; Cell count: 60.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-B6-A408-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 1; Percent necrosis: 1; Percent stromal cells: 23; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-B6-A408-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Her2 cent17 ratio: 1.2; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Mixed Histology (please specify); Histologic diagnosis other: ductal and lobular; Micromet detection by IHC: No; Er IHC score: 3+; Her2 IHC score: 2+; Method initial path diagnosis: Tumor resection; Prospective collection: No; Retrospective collection: Yes; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,072 days; disease-specific survival: no event (censored), 2,072 days; disease-free interval: no event (censored), 2,072 days; progression-free interval: no event (censored), 2,072 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B6-A408-01A-12D-A242-01): tumor purity 0.57, ploidy 3.43, whole-genome doublings 1.
